Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5879, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5879-01A (Primary Tumor).

[page 1 of 4]
Patient Name

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

large right renal mass and retroperitoneal lymphadenopathy with outside bx showing collecting duct CA.

Specimens Submitted:

- 1: Kidney, right, total nephrectomy
- 2: Lymph nodes, interaortocaval and presacral, excision
- 3: Lymph nodes, interaortocaval #2, excision
- 4: Right adrenal gland, paracaval and retrocaval lymph nodes, excision
- 5: Lymph nodes, para-aortic, excision
- 6: Lymph nodes, right suprahilar, excision

DIAGNOSIS:

1. Kidney, right, total nephrectomy

Tumor Type:

Renal cell carcinoma - Unclassified type
High grade. See comment.

Tumor Size:

Greatest diameter is 9.2 cm.

Local Invasion (for renal cortical types):

Extends into renal pelvis
Involves renal hilar fat

Local Invasion (for renal pelvic tumors):

Involves renal hilar fat

Renal Vein Invasion:

Not identified
Tumor is present within medium sized vessels in the renal hilum

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

[page 2 of 4]
Comment: The tumor cells are reactive for CD10, RCC, racemase, and e-cadherin. They are negative for CK7, CK20, and 34BE12. Despite the unusual morphologic and immunohistochemical features, this is likely to represent a so-called collecting duct carcinoma.

2. Lymph nodes, interaortacaval and presacral, excision [REDACTED]
Lymph Nodes:
Matted lymph nodes positive for metastatic carcinoma

3. Lymph nodes, interaortacaval #2, excision [REDACTED]
Lymph Nodes:
Matted lymph nodes positive for metastatic carcinoma

4. Right adrenal gland, paracaval and retrocaval lymph nodes, excision [REDACTED]
Adrenal gland negative for carcinoma.
Matted lymph nodes positive metastatic carcinoma.
Three of eleven lymph nodes positive for metastatic carcinoma [REDACTED]

5. Lymph nodes, para-aortic, excision [REDACTED]
Lymph Nodes:
Not involved
Number of nodes examined:5

6. Lymph nodes, right suprahilar, excision [REDACTED]
Lymph Nodes:
Not involved
Number of nodes examined:10
Minute fragment of adrenal cortical tissue

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT

Special Studies:

Result

Special Stain

Comment

CK7
CK20
34BE12
CD10
RCC
MUCIN
E-CADHERIN
NEG CONT
IMM RECUT
RACEMASE
NEG CONT
IMM RECUT
CK5/6
CK8
CK18

[page 3 of 4]
[REDACTED]

Gross Description:

[REDACTED]

1). The specimen is received fresh labeled "right kidney tumor" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 567 g in total. The kidney measures 11.4 x 9.2 x 7.5 cm. The attached ureter measures 1.7 cm in length and 0.4 cm in diameter. The attached renal vein measures 1.2 cm in length and 0.3 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a heterogeneous mass centered in the cortex of the midsection of the kidney measuring 9.2 x 7.5 x 7.0 cm. Parts of the tumor are myxoid and gelatinous, while other areas show tan-yellow fleshy tissue. The tumor extends into the capsule of the kidney and pushes into the hilum with focal extension into the renal pelvis. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined corticomedullary junction. The cortex measures 0.9 cm and the calyces appear normal. * lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

FSC-frozen section control

UVM -- ureteral and vessel margins

T-- tumor

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

RP -- renal pelvis representative sections

K -- representative sections kidney

PLN-possible lymph nodes

[REDACTED]

2). The specimen is received in formalin labeled "interaortocaval lymph nodes". It consists of a tan soft tissue mass measuring 5.0 x 4.0 x 2.5 cm. The cut surface shows a tan and yellow soft tissue mass with necrosis and hemorrhage. Representative sections are submitted.

Summary sections:

ST-soft tissue

[REDACTED]

3). The specimen is received in formalin labeled "interaortocaval lymph nodes number two". It consists of a tan soft tissue fragment measuring 4.1 x 2.5 x 2.0 cm. The specimen is sectioned to reveal a tan and yellow necrotic mass. Representative sections are submitted.

Summary of sections:

ST-soft tissue

[REDACTED]

4). The specimen is received fresh labeled "right adrenal gland, paracaval and retrocaval lymph nodes". It consists of an adrenal gland and attached soft tissue weighing 69 g and measuring 7.5 x 6.5 x 3.4 cm in overall. The adrenal gland measures 5.8 x 4.1 x 1.0 cm. The cut surface of the adrenal gland is grossly unremarkable. The soft tissue is sectioned to reveal matted grossly positive lymph nodes. Multiple smaller lymph nodes are identified ranging from 1.1 to 1.5 cm in greatest dimension. Representative sections of the adrenal gland are submitted along with representative sections of the matted lymph nodes. The smaller lymph nodes are entirely submitted. Tissue is given for TPS.

Summary of sections:

AG-adrenal gland

MLN-matted lymph nodes

LN-lymph nodes

[REDACTED]

5). It consists of fatty soft tissue measuring 3.5 x 1.5 x 1.2 cm. Multiple lymph nodes are identified ranging from 0.3 to 0.8 cm in greatest dimension. The tissue is entirely submitted.

Summary sections:

LN-lymph nodes

[page 4 of 4]
6). The specimen is received in formalin labeled "right suprahilar lymph node". It consists of multiple fragments of tan and fatty soft tissue measuring 3.2 x 2.0 x 1.4 cm in aggregate. Multiple lymph nodes are identified ranging from 0.3 to 0.5 cm in greatest dimension. The tissue is entirely submitted.

Summary of sections:
LN-lymph nodes

Summary of Sections:

Part 1: Kidney, right, total nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	k	1
1	pln	1
1	rp	1
8	t	8
1	thf	1
1	tk	1
1	tsf	1
1	uvm	1

Part 2: Lymph nodes, interaortocaval and presacral, excision

Block	Sect. Site	PCs
2	st	2

Part 3: Lymph nodes, interaortocaval #2, excision

Block	Sect. Site	PCs
2	st	2

Part 4: Right adrenal gland, paracaval and retrocaval lymph nodes, excision

Block	Sect. Site	PCs
1	ag	2
3	ln	3
2	mln	2

Part 5: Lymph nodes, para-aortic, excision

Block	Sect. Site	PCs
2	ln	2

Part 6: Lymph nodes, right suprahilar, excision

Block	Sect. Site	PCs
2	ln	2

Intraoperative Consultation:

The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation

- 1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA, CANNOT TYPE.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file b7d2466d-9629-4d0c-956c-8ba05df54574 (TCGA-BQ-5879.45E7A619-4DE8-4015-95CA-5BB8190B395E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).